Somatic mutation profile of tumor specimen MMRF_2246_1_BM_CD138pos (aliquot MMRF_2246_1_BM_CD138pos_T1_KHS5U_L09543) from MMRF case MMRF_2246, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.5 years (23,938 days).
Specimen MMRF_2246_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b2b41696-b702-44e6-9cad-c76aeefb10cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2246_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2246_1_PB_Whole_C2_KHS5U_L09544; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db2cfe63-2bb4-481c-9c20-173f27a949d1

The open-access MAF lists 81 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 22, Silent 11, Intron 9, 3'Flank 3, 5'UTR 2, Frame Shift Del 2, Nonsense Mutation 1, 5'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 40/84 reads (48%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ADAMTS7 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs200778107; called by muse, mutect2, varscan2
- ARID4B | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 5/56 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51598779; called by muse, mutect2
- CDH10 | c.2054del p.K685Sfs*34 | Frame Shift Del (DEL) | VAF 37/119 reads (31%) | catalogued as rs1561116064; called by mutect2, pindel, varscan2
- CDH26 | c.2027C>T p.S676L (on ENST00000348616 / NM_177980.4; = p.S9L on NM_021810.6) | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV54842129; called by muse, mutect2, varscan2
- CEACAM20 | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100386807; called by muse, mutect2, varscan2
- CPXM1 | c.2095G>A p.V699M | Missense Mutation (SNP) | VAF 37/97 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.13); catalogued as rs560382916, COSV66044754; called by muse, mutect2, varscan2
- FSHR | c.1866C>A p.N622K | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV58638435; called by muse, mutect2, varscan2
- HPGD | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56661673; called by muse, mutect2, varscan2
- IFT140 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.706); catalogued as rs150649451; called by muse, mutect2, varscan2
- NLRP8 | c.1984G>A p.V662I | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as rs371255067; called by muse, mutect2, varscan2
- OR2T34 | c.640A>G p.T214A | Missense Mutation (SNP) | VAF 98/738 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs145854970; called by muse, mutect2, varscan2
- PCLO | c.12728T>G p.F4243C | Missense Mutation (SNP) | VAF 41/133 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100428051; called by muse, mutect2, varscan2
- RBM44 | c.198+1G>A p.X66_splice (on ENST00000611254; = p.X700_splice on NM_001080504.2) | Splice Site (SNP) | VAF 24/53 reads (45%) | catalogued as COSV57628548; called by muse, mutect2, varscan2
- AARS1 | c.1814A>G p.H605R | Missense Mutation (SNP) | VAF 22/39 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF2 | c.1435A>G p.K479E | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- C20orf194 | c.594T>A p.F198L | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CCDC166 | c.635C>A p.A212E | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- GJE1 | c.109G>T p.G37W | Missense Mutation (SNP) | VAF 36/89 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JUNB | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- KANSL1L | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- MAP3K3 | c.1599G>C p.W533C | Missense Mutation (SNP) | VAF 36/68 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP26 | c.511T>G p.L171V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NF2 | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- QRFPR | c.835G>C p.V279L | Missense Mutation (SNP) | VAF 55/449 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RFPL4AL1 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 32/230 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- RFWD3 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPEF2 | c.1829T>G p.V610G | Missense Mutation (SNP) | VAF 87/125 reads (70%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- STRBP | c.634del p.A212Qfs*4 | Frame Shift Del (DEL) | VAF 38/153 reads (25%) | called by mutect2, pindel, varscan2
- TENT5C | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 12/160 reads (8%) | called by muse, mutect2
- TENT5C | c.693C>G p.I231M | Missense Mutation (SNP) | VAF 32/176 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOP1MT | c.1696A>G p.I566V | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VANGL2 | c.796C>A p.L266I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH6 | c.1527C>A p.L509= | Silent (SNP) | VAF 41/96 reads (43%) | called by muse, mutect2, varscan2
- GFRA1 | c.1233A>G p.T411= | Silent (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- IGHV2-5 | c.57C>G p.S19= | Silent (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- IGHV2-70 | c.324T>G p.P108= | Silent (SNP) | VAF 14/35 reads (40%) | catalogued as rs576277090; called by muse, varscan2
- IGHV2-70 | c.258C>T p.T86= | Silent (SNP) | VAF 39/85 reads (46%) | catalogued as rs373266582; called by muse, varscan2
- LPCAT1 | c.525G>A p.V175= | Silent (SNP) | VAF 70/112 reads (63%) | called by muse, mutect2, varscan2
- NCKAP5 | c.2163G>A p.Q721= | Silent (SNP) | VAF 55/109 reads (50%) | called by muse, mutect2, varscan2
- PAX6 | c.180T>C p.Y60= | Silent (SNP) | VAF 174/555 reads (31%) | called by muse, mutect2, varscan2
- PTPRJ | c.2475T>C p.I825= | Silent (SNP) | VAF 64/109 reads (59%) | called by muse, mutect2, varscan2
- SLC34A2 | c.492G>A p.T164= | Silent (SNP) | VAF 41/93 reads (44%) | catalogued as rs747225604, COSV65941412; called by muse, mutect2, varscan2
- STYXL2 | c.1689G>A p.A563= | Silent (SNP) | VAF 102/161 reads (63%) | catalogued as rs753536435, COSV99609396, COSV99609861; called by muse, mutect2, varscan2
- ARHGAP26 | c.*399G>C | 3'UTR (SNP) | VAF 39/152 reads (26%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130914972 G>A | 5'Flank (SNP) | VAF 58/146 reads (40%) | called by muse, mutect2, varscan2
- BZW1 | c.-10-209del | Intron (DEL) | VAF 17/136 reads (13%) | called by mutect2, pindel, varscan2
- CABP7 | c.*98G>A | 3'UTR (SNP) | VAF 5/27 reads (19%) | catalogued as rs936395689; called by muse, mutect2, varscan2
- CCDC174 | c.*965A>G | 3'UTR (SNP) | VAF 45/76 reads (59%) | called by muse, mutect2, varscan2
- CPLX2 | c.*3103_*3108del | 3'UTR (DEL) | VAF 82/149 reads (55%) | called by mutect2, pindel, varscan2
- DNMBP | c.*1366G>C | 3'UTR (SNP) | VAF 39/97 reads (40%) | called by muse, mutect2, varscan2
- DUSP2 | c.*6T>A | 3'UTR (SNP) | VAF 15/32 reads (47%) | catalogued as rs1323184104; called by muse, mutect2, varscan2
- EPB41L4A | c.*495C>G | 3'UTR (SNP) | VAF 17/53 reads (32%) | called by muse, mutect2, varscan2
- GCNT2 | c.926-35442G>A | Intron (SNP) | VAF 115/190 reads (61%) | called by muse, mutect2, varscan2
- GJB2 | c.*1119C>T | 3'UTR (SNP) | VAF 35/77 reads (45%) | called by muse, mutect2, varscan2
- HM13 | c.-52G>A | 5'UTR (SNP) | VAF 30/48 reads (63%) | called by muse, mutect2, varscan2
- HTN1 | c.*8A>C | 3'UTR (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- IGF2 | chr11:2131221 G>C | 3'Flank (SNP) | VAF 52/178 reads (29%) | called by muse, mutect2, varscan2
- LONRF2 | c.*7584G>A | 3'UTR (SNP) | VAF 30/54 reads (56%) | called by muse, mutect2, varscan2
- LOXL3 | c.*358A>C | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- MGAM | c.4619-7920T>C | Intron (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- NAA15 | c.*1058_*1060del | 3'UTR (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- NEGR1 | c.*12C>G | 3'UTR (SNP) | VAF 76/149 reads (51%) | catalogued as rs749013935; called by muse, mutect2, varscan2
- NFAT5 | c.73+2164A>G | Intron (SNP) | VAF 16/31 reads (52%) | catalogued as rs758201876; called by muse, mutect2, varscan2
- NPAP1 | c.*2772A>C | 3'UTR (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110171834 T>G | 3'Flank (SNP) | VAF 6/124 reads (5%) | called by muse, mutect2
- PCDH11X | c.3033+199G>T | Intron (SNP) | VAF 104/131 reads (79%) | called by muse, mutect2, varscan2
- PCDHB6 | chr5:141156520 C>T | 3'Flank (SNP) | VAF 92/365 reads (25%) | called by muse, mutect2, varscan2
- PIAS1 | c.934+38_934+42del | Intron (DEL) | VAF 8/36 reads (22%) | called by mutect2, pindel
- PNLIPRP1 | c.204+79C>T | Intron (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- RAB3IP | c.*2584C>G | 3'UTR (SNP) | VAF 39/95 reads (41%) | called by muse, mutect2, varscan2
- RSBN1 | c.*2026A>T | 3'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs943627236, COSV99792880; called by muse, mutect2
- SCUBE2 | c.*746G>T | 3'UTR (SNP) | VAF 7/28 reads (25%) | called by mutect2, varscan2
- SIAH2 | c.-41G>A | 5'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- SLC10A2 | c.*371G>T | 3'UTR (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- SPIRE1 | c.*3014G>C | 3'UTR (SNP) | VAF 40/50 reads (80%) | called by muse, mutect2, varscan2
- SRPK1 | c.*1947G>A | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs958275225; called by muse, mutect2
- TCL1A | c.*6+23C>T | Intron (SNP) | VAF 100/240 reads (42%) | catalogued as rs779872846, COSV68085119; called by muse, varscan2
- TTC39A | c.1162-2032G>T | Intron (SNP) | VAF 11/164 reads (7%) | called by muse, mutect2
- UBE2E2 | c.*809G>A | 3'UTR (SNP) | VAF 22/62 reads (35%) | called by muse, mutect2, varscan2
- VGLL3 | c.*370C>G | 3'UTR (SNP) | VAF 21/58 reads (36%) | called by muse, mutect2, varscan2
